Somatic mutation profile of tumor specimen TCGA-BR-8590-01A (aliquot TCGA-BR-8590-01A-11D-2394-08) from TCGA case TCGA-BR-8590, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 62.8 years (22,937 days).
Specimen TCGA-BR-8590-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00eb9331-7818-400b-912e-75081001a1c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8590-10A (Blood Derived Normal), aliquot TCGA-BR-8590-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd85b3a0-fa89-4908-a82d-c0ad114060a4

The open-access MAF lists 112 somatic variants for this specimen: 87 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 21, Frame Shift Del 4, Nonsense Mutation 3, 3'UTR 2, Splice Region 2, RNA 1, Splice Site 1, Frame Shift Ins 1, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB4 | c.3305T>G p.F1102C | Missense Mutation (SNP) | VAF 11/125 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100728834, COSV61461348; called by muse, mutect2
- ABCC9 | c.2144T>C p.L715P | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53975931; called by muse, mutect2, varscan2
- ABCD1 | c.597G>T p.E199D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.253); catalogued as COSV54385756; called by muse, mutect2, varscan2
- ABCF1 | c.956T>C p.F319S (on ENST00000326195 / NM_001025091.2; = p.F281S on NM_001090.3) | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV58229588; called by muse, mutect2, varscan2
- ACTL9 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 17/80 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV100185089; called by muse, mutect2, varscan2
- ACTRT1 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64419626; called by muse, mutect2, varscan2
- ADCY8 | c.3068G>T p.G1023V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV99650465; called by muse, mutect2
- AMPD1 | c.1505A>C p.K502T | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as COSV62416774; called by muse, mutect2
- ATP13A5 | c.3121A>G p.S1041G | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV60870941; called by muse, mutect2, varscan2
- C12orf40 | c.18del p.S7Pfs*6 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as COSV61129099; called by mutect2, pindel, varscan2
- CCDC27 | c.1139G>T p.R380M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV53901160; called by muse, mutect2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | catalogued as rs751492244; called by mutect2, varscan2
- CNKSR2 | c.2291A>G p.Q764R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV54259169; called by muse, mutect2, varscan2
- CPNE1 | c.384G>A p.T128= (on ENST00000352393; = p.T133= on NM_003915.5) | Splice Region (SNP) | VAF 4/42 reads (10%) | catalogued as rs376888862; called by mutect2, varscan2
- CRP | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.155); catalogued as COSV54813862, COSV54814971; called by muse, varscan2
- CSMD3 | c.484A>G p.S162G | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV52216988; called by muse, mutect2, varscan2
- CST5 | c.149T>A p.F50Y | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); catalogued as COSV59014749; called by muse, mutect2
- CSTL1 | c.139T>G p.F47V | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV55678347; called by muse, mutect2
- CYB5A | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.654); catalogued as COSV55022229; called by muse, mutect2
- DCC | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59107399; called by muse, mutect2
- DNAH9 | c.11257A>C p.T3753P | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV52356645; called by muse, mutect2
- EPC1 | c.1348A>G p.R450G | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV99552495; called by muse, mutect2
- FAT4 | c.13214T>C p.I4405T | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV58691881; called by muse, mutect2
- FMN2 | c.2762del p.P921Lfs*354 | Frame Shift Del (DEL) | VAF 16/142 reads (11%) | catalogued as COSV60455969; called by pindel, varscan2
- FOXD1 | c.386C>G p.S129W | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61076596; called by muse, mutect2
- GLOD4 | c.289C>T p.L97F (on ENST00000301328 / NM_001366247.1; = p.L82F on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV56754021; called by muse, mutect2
- GLRA2 | c.686T>G p.L229R | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54342632; called by muse, mutect2, varscan2
- GPAA1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs369617537, COSV60155766; called by muse, mutect2, varscan2
- GRXCR1 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as COSV67669907; called by muse, mutect2, varscan2
- HAPLN4 | c.123G>A p.E41= | Splice Region (SNP) | VAF 3/33 reads (9%) | catalogued as rs1307276806, COSV52270083; called by muse, mutect2
- HESX1 | c.421T>A p.L141I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55843381; called by muse, mutect2
- HTR1B | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.499); catalogued as rs1562136012, COSV64051605; called by muse, mutect2
- KCNF1 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs1357532034, COSV54464136, COSV54465168; called by muse, mutect2
- KDM2B | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV65642279; called by muse, mutect2
- KIFBP | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62831906; called by muse, mutect2, varscan2
- KMT2A | c.8444C>T p.P2815L | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as rs781858437, COSV63287729; called by muse, mutect2, varscan2
- KRT1 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs60359468, COSV52867041; ClinVar: not provided; called by muse, mutect2, varscan2
- KRT73 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs371740648, COSV59838302; called by muse, mutect2, varscan2
- LRP5 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.964); catalogued as rs748168729, COSV53715837; called by muse, mutect2, varscan2
- LRRK2 | c.3850T>G p.F1284V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV54157626; called by muse, mutect2, varscan2
- MARCHF9 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as rs372403968; called by muse, mutect2, varscan2
- MBNL2 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.657); catalogued as COSV59122426; called by muse, mutect2, varscan2
- MED30 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs747290267, COSV99815916; called by muse, mutect2, varscan2
- MPRIP | c.2543T>G p.L848R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57928126; called by muse, mutect2, varscan2
- MYO3A | c.270A>C p.K90N | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV56319836; called by muse, mutect2, varscan2
- NDST3 | c.704T>G p.F235C | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV56621645; called by muse, mutect2
- OAS2 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs754539372, COSV60802997; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2M2 | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 23/314 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV62898650; called by muse, mutect2
- OR2M4 | c.647T>G p.L216R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV60708597; called by muse, mutect2
- OR4C11 | c.692A>C p.K231T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV56353846; called by muse, varscan2
- OR4C11 | c.619A>C p.S207R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV56353063, COSV56353716; called by muse, varscan2
- OR51A7 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV63787997, COSV63788424; called by muse, mutect2
- OR52K1 | c.217T>A p.L73M | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56903960, COSV56905016; called by muse, mutect2, varscan2
- OR5M10 | c.676T>G p.F226V | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1456563927, COSV73242250, COSV73242441; called by muse, mutect2
- OR5P3 | c.493A>G p.R165G | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1351783142, COSV60429462; called by muse, mutect2, varscan2
- OR6K3 | c.295T>C p.S99P (on ENST00000368146; = p.S83P on NM_001005327.2) | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV63745835; called by muse, mutect2
- OSBPL6 | c.2759G>A p.R920Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs759571487, COSV51913807; called by muse, mutect2, varscan2
- PABPC5 | c.987T>A p.S329R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV57041494; called by muse, varscan2
- PCDH15 | c.4368-2A>C p.X1456_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100214232; called by muse, mutect2, varscan2
- PCDHA8 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.053); catalogued as COSV65338136; called by muse, mutect2
- PCDHB1 | c.899A>T p.E300V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV60631655; called by muse, mutect2
- PCDHGA12 | c.1498A>G p.S500G | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.21); catalogued as COSV52755956; called by muse, mutect2
- PES1 | c.242A>C p.K81T | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as COSV58829028; called by muse, mutect2
- PPIAL4G | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV70087034; called by muse, mutect2
- PRKAR1A | c.749T>G p.L250R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62235888; called by muse, mutect2, varscan2
- RELN | c.1007G>C p.G336A | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.352); catalogued as COSV59011173; called by muse, mutect2
- ROS1 | c.6423A>C p.Q2141H | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV63856755; called by muse, mutect2
- SCN10A | c.2727C>G p.N909K | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV71861848, COSV71862794; called by muse, mutect2
- SH3TC1 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs766716993, COSV55285873; called by muse, mutect2, varscan2
- SIGLEC12 | c.1122A>T p.Q374H (on ENST00000291707 / NM_053003.4; = p.Q256H on NM_033329.2) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.249); catalogued as COSV52462490; called by muse, mutect2, varscan2
- SPTBN5 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs755228815, COSV58023057; called by muse, mutect2, varscan2
- STAB1 | c.6667T>G p.F2223V | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58738481; called by muse, mutect2, varscan2
- STYK1 | c.965T>C p.L322P | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50013707; called by muse, mutect2
- TAF8 | c.919A>T p.K307* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV65896357; called by muse, mutect2, varscan2
- TASOR2 | c.437A>G p.K146R | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV60168104; called by muse, mutect2
- TEK | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66229856; called by muse, mutect2
- TENM2 | c.1356A>C p.E452D (on ENST00000518659 / NM_001122679.2; = p.E220D on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1562110996, COSV69124301, COSV69136431; called by muse, mutect2, varscan2
- TMA16 | c.469A>C p.K157Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV56819550, COSV99919548; called by muse, mutect2, varscan2
- TNNI1 | c.374G>C p.R125P | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60189821; called by muse, mutect2, varscan2
- UBE3A | c.575A>C p.E192A | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV51667180; called by muse, mutect2
- WDR19 | c.935T>C p.I312T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs886059396, COSV56466563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- YAP1 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs746188462, COSV56776058; called by muse, mutect2, varscan2
- ZMYND19 | c.375T>G p.Y125* | Nonsense Mutation (SNP) | VAF 17/225 reads (8%) | catalogued as COSV53022577; called by muse, mutect2
- ZNF578 | c.1360T>C p.S454P | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1424316431, COSV69736046; called by muse, mutect2, varscan2
- ZNF585A | c.761A>G p.K254R (on ENST00000292841 / NM_001288800.2; = p.K199R on NM_152655.3) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV53064827, COSV99492776; called by muse, varscan2
- SLC12A3 | c.923dup p.S309Ifs*2 | Frame Shift Ins (INS) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- AGXT2 | c.1227A>G p.E409= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV51487577; called by muse, mutect2
- ANKRD13C | c.516G>A p.V172= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV52032560; called by muse, mutect2
- BDP1 | c.5070A>C p.G1690= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV62432192; called by muse, mutect2
- CMIP | c.2121G>A p.S707= (on ENST00000537098 / NM_198390.2; = p.S613= on NM_030629.3) | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs376548023; called by muse, mutect2, varscan2
- DDX54 | c.1536T>C p.A512= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs567559025, COSV58374422; called by muse, mutect2, varscan2
- FLRT2 | c.69C>A p.S23= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV100421053, COSV58144233; called by muse, mutect2, varscan2
- FOXN1 | c.195A>C p.P65= | Silent (SNP) | VAF 15/149 reads (10%) | catalogued as COSV56882472; called by muse, mutect2
- FOXP2 | c.1332T>G p.P444= | Silent (SNP) | VAF 11/142 reads (8%) | catalogued as COSV63488226; called by muse, mutect2
- IFIT1B | c.348T>G p.T116= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV65663534; called by muse, mutect2
- KRT6A | c.378C>A p.G126= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100416650; called by muse, varscan2
- LRP1B | c.11370T>G p.G3790= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- LRP1B | c.888T>C p.N296= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV67237140; called by muse, mutect2
- MUC16 | c.37854C>T p.H12618= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs750755002, COSV101197792; called by muse, varscan2
- MYH6 | c.2109C>A p.G703= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV100676217; called by muse, mutect2
- NLE1 | c.813C>T p.V271= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV62604527; called by muse, mutect2
- NLK | c.1290G>A p.G430= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs755786504, COSV69409485; called by muse, mutect2, varscan2
- PCDHA10 | c.1098C>T p.T366= | Silent (SNP) | VAF 15/175 reads (9%) | catalogued as rs1554149571, COSV56515778; called by muse, mutect2
- PITPNM3 | c.1674C>T p.C558= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2
- PRB2 | c.636T>G p.P212= | Silent (SNP) | VAF 54/448 reads (12%) | catalogued as COSV101231361, COSV66983586; called by muse, varscan2
- SLCO2A1 | c.1479C>T p.S493= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV60486759; called by muse, mutect2
- ZNF829 | c.660T>C p.A220= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV66986586; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1074A>C | 3'UTR (SNP) | VAF 13/77 reads (17%) | catalogued as COSV57543309; called by muse, mutect2, varscan2
- DCHS2 | n.2120C>T | RNA (SNP) | VAF 12/154 reads (8%) | catalogued as COSV59729916; called by muse, mutect2
- MSI2 | c.63-52A>T | Intron (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99401480; called by muse, mutect2
- ZNF99 | c.*581A>C | 3'UTR (SNP) | VAF 9/49 reads (18%) | catalogued as COSV68055986; called by muse, varscan2
